Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4367, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4367-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Antrum. Tumor configuration: Ulcerating. Tumor size: 7 x 6 x 2 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Not specified. Lymph nodes: 2 of 8 positive for metastasis. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 83b6bf4e-bce7-4cee-80e3-e2d045009a34 (TCGA-BR-4367.2BA4103D-DF1B-4B35-8398-A3879ADBD0CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).